Somatic mutation profile of tumor specimen 0DKF9Z from CCDI case PBBWUD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 16.7 years (6,096 days).
Specimen 0DKF9Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae26640d-b1da-4ae6-8aec-72d2eebfed13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKF9K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/455d1874-708a-4815-ae81-3ae99a7d581b

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRB1 | c.838G>A p.V280I | Missense Mutation (SNP) | VAF 78/410 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1221382536; called by muse, varscan2
- GJD2 | c.476A>G p.N159S | Missense Mutation (SNP) | VAF 58/506 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs766322223; called by muse, varscan2
- PLXNA1 | c.1024G>T p.A342S | Missense Mutation (SNP) | VAF 76/398 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.059); catalogued as rs1396875238, COSV52531427; called by muse, varscan2
- RPS6KA5 | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 167/1091 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1220407517; called by muse, varscan2
- TRAFD1 | c.1027C>A p.Q343K | Missense Mutation (SNP) | VAF 72/506 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as rs867140222, COSV57505846; called by muse, varscan2
- FAM117A | c.638G>T p.S213I | Missense Mutation (SNP) | VAF 259/1496 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- GUCA1B | c.556C>G p.P186A | Missense Mutation (SNP) | VAF 164/1001 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, varscan2
- MYO1B | c.*59T>C | 3'UTR (SNP) | VAF 146/540 reads (27%) | called by muse, varscan2
- ZNF829 | c.-9T>A | 5'UTR (SNP) | VAF 179/1109 reads (16%) | called by muse, varscan2
